Somatic mutation profile of tumor specimen 0DFWCD from CCDI case PBBSRE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 10.6 years (3,879 days).
Specimen 0DFWCD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5507e4cd-314e-4c2c-b2b8-0ff1a6aaba1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFWCE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c57be3a-ef9e-4a26-a4ff-ecaec3c9c209

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 5'Flank 1, Nonsense Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH3 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 37/419 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs965795475, COSV99767242; called by muse, mutect2
- FAM153B | c.259+5G>A | Splice Region (SNP) | VAF 48/192 reads (25%) | catalogued as rs373938943; called by muse, mutect2, varscan2
- RBM46 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 134/345 reads (39%) | catalogued as rs866164836, COSV55977357; called by muse, mutect2, varscan2
- SNX21 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 264/598 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs144014614; called by muse, mutect2, varscan2
- HUWE1 | c.9881T>A p.L3294Q | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NALCN | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 47/473 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- NSRP1 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 158/363 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TM9SF2 | c.1325C>A p.P442H | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSRR | c.1089C>T p.N363= | Silent (SNP) | VAF 76/207 reads (37%) | called by muse, mutect2, varscan2
- OPN4 | c.906C>T p.I302= | Silent (SNP) | VAF 167/398 reads (42%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5893003 G>A | 5'Flank (SNP) | VAF 65/128 reads (51%) | catalogued as rs1319178910; called by muse, mutect2, varscan2
- LILRA2 | c.1255+1380C>A | Intron (SNP) | VAF 102/291 reads (35%) | called by muse, mutect2, varscan2
